Somatic mutation profile of tumor specimen ALCH-B4XC-TTP1-A (aliquot ALCH-B4XC-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4XC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.8 years (25,845 days).
Specimen ALCH-B4XC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e2abfb0-32d5-416e-840e-522003245cdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4XC-NB1-A (Blood Derived Normal), aliquot ALCH-B4XC-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f26606-835f-4d69-b345-7ccee61853ba

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Ins 1, 5'Flank 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 24/281 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- NSD1 | c.4889A>G p.N1630S | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs1312980715; called by muse, mutect2
- PRMT6 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV63656128; called by muse, mutect2, varscan2
- CAGE1 | c.1759A>G p.T587A (on ENST00000512086; = p.T451A on NM_205864.3) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.036); called by muse, mutect2
- FNTB | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- MGST2 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- PPP1R16A | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.143); called by muse, mutect2
- RCC1 | c.204T>A p.D68E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPR | c.5138dup p.T1714Nfs*39 | Frame Shift Ins (INS) | VAF 8/87 reads (9%) | called by mutect2, pindel, varscan2
- TRO | c.45+4A>C | Splice Region (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- ZNF396 | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DIPK2A | c.1032A>G p.S344= | Silent (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- KAT8 | c.807T>G p.L269= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- PPP1R16A | c.549G>A p.L183= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1035445995; called by muse, mutect2, varscan2
- TRPA1 | c.3060C>T p.F1020= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV51555312; called by muse, mutect2, varscan2
- FAM193A | chr4:2625318 T>C | 5'Flank (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- MEST | c.181+650T>G | Intron (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
